Somatic mutation profile of tumor specimen TCGA-WY-A85A-01A (aliquot TCGA-WY-A85A-01A-21D-A36O-08) from TCGA case TCGA-WY-A85A, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 20.2 years (7,380 days).
Specimen TCGA-WY-A85A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e46ec2d2-b87a-450d-86a5-506dbf08274c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WY-A85A-10A (Blood Derived Normal), aliquot TCGA-WY-A85A-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b053a038-c63b-4adb-8af6-ff48f02381c0

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 6, Silent 5, Frame Shift Del 3, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD5 | c.3203G>A p.G1068E | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100429689; called by muse, mutect2, varscan2
- ATRX | c.5787-2A>C p.X1929_splice | Splice Site (SNP) | VAF 91/118 reads (77%) | catalogued as COSV100970140; called by muse, mutect2, varscan2
- CHAT | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100339814; called by muse, mutect2
- KCNJ15 | c.923G>A p.G308D | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100154038; called by muse, mutect2, varscan2
- MUTYH | c.1435del p.H479Tfs*9 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | catalogued as COSV58343868; called by mutect2, pindel, varscan2
- OR52L1 | c.983A>G p.K328R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as rs747040030, COSV100176048; called by muse, varscan2
- RALGAPA2 | c.5055G>A p.V1685= | Splice Region (SNP) | VAF 9/24 reads (38%) | catalogued as rs1179961396, COSV99173171; called by muse, varscan2
- SMARCA4 | c.2731G>T p.G911C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758185, COSV60798378; called by muse, mutect2, varscan2
- STIL | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1219432309, COSV99680613; called by muse, mutect2, varscan2
- COL11A1 | c.194_197del p.K65Ifs*40 | Frame Shift Del (DEL) | VAF 31/97 reads (32%) | called by pindel, varscan2
- ZEB2 | c.79_80del p.N27Lfs*2 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- ABL2 | c.1938G>A p.R646= (on ENST00000502732 / NM_007314.4; = p.R631= on NM_005158.5) | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV100772499; called by muse, mutect2
- ARHGEF19 | c.1998C>T p.H666= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs770588521, COSV54615976, COSV99580085; called by mutect2, varscan2
- MYH7 | c.3666C>T p.S1222= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs397516191, COSV62523006; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHGB7 | c.1623G>A p.A541= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99531646; called by muse, mutect2, varscan2
- TRPC6 | c.201G>A p.R67= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs372852515; called by muse, mutect2, varscan2
